Gene-level copy-number profile of tumor specimen TCGA-CN-6994-01A from TCGA case TCGA-CN-6994, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 67.8 years (24,778 days).
Specimen TCGA-CN-6994-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.38341d1d-6b61-45c5-9f80-31c0c6896441.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-6994-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1d6d57cf-c9c5-4431-a0b3-9aae415d33c9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 135; copy number 2: 8,406; copy number 3: 21,341; copy number 4: 17,889; copy number 5: 3,747; copy number 6: 2,568; copy number 7: 3,723; copy number 8: 1,712; copy number 9: 50; copy number 10: 2; copy number 12: 83; copy number 13: 40; copy number 21: 4; copy number 22: 9; copy number 23: 47; copy number 32: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-6994-01A-11D-1910-01): tumor purity 0.58, ploidy 3.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,725 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:197,804,593–198,572,581, 1 gene, copy number 21 (within-gene range 6–21): PLCL1.
- chr2:198,187,802–198,772,356, 3 genes, copy number 21: AC020719.1, LINC01923, AC019330.1.
- chr3:99,638,475–198,222,513, 1,718 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr5:173,225,836–175,710,756, 47 genes, copy number 7: RPL7AP33, NKX2-5, Y_RNA, RNA5SP200, STC2, MIR8056, RNU6-500P, AC016573.1, AC008632.1, AC008663.1, AC008663.3, AC008663.2, BOD1, LINC01863, LINC01942, LINC01484, AC008674.1, LINC01485, CPEB4, C5orf47, RPL12P22, NSG2, AC113423.1, AC113423.2, AC011333.1, AC025752.1, LINC01411, GAPDHP71, SUMO2P6, AC108112.1, HIGD1AP3, MSX2, AC113346.2, MIR4634, AC113346.1, LINC01951, NIFKP2, AC008413.1, AC008413.2, ARL2BPP6, DRD1, AC091393.2, SFXN1, AC091393.1, RN7SKP148, HRH2, RNU6-226P.
- chr8:84,665,759–138,497,261, 752 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr11:27,040,725–27,484,128, 6 genes, copy number 12 (within-gene range 4–12): BBOX1, BBOX1-AS1, CCDC34, LGR4, LGR4-AS1, AC100771.1.
- chr11:45,647,689–46,739,506, 37 genes, copy number 13: CHST1, AC087442.1, MIR7154, AC044839.1, AC044839.2, LINC02690, LINC02716, SLC35C1, AC044839.3, CRY2, MAPK8IP1, AC068385.1, C11orf94, PEX16, LARGE2, PHF21A, AC024475.1, AC024475.3, AC024475.2, LINC02710, AC116021.1, LINC02489, CREB3L1, DGKZ, MIR4688, MDK, CHRM4, AMBRA1, AC024293.1, MIR3160-1, MIR3160-2, AC127035.1, HARBI1, ATG13, ARHGAP1, ZNF408, F2.
- chr11:46,753,125–46,762,499, 3 genes, copy number 13: MIR5582, AC115088.1, SNORD67.
- chr11:68,683,779–76,804,555, 282 genes, copy number 7–32 (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 7 (broad region; genes not listed).
- chr12:38,544,177–44,503,596, 78 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr12:57,128,483–57,213,361, 1 gene, copy number 8 (within-gene range 5–8): LRP1.
- chr12:57,194,504–66,343,643, 201 genes, copy number 8 (broad region; genes not listed).
- chr12:66,563,524–66,569,194, 2 genes, copy number 8: OSBPL9P5, OSBPL9P4.
- chr12:68,272,443–68,332,381, 1 gene, copy number 7 (within-gene range 1–7): MDM1.
- chr12:68,344,664–68,349,959, 1 gene, copy number 7: AC022511.1.
- chr14:21,585,290–21,602,825, 2 genes, copy number 10: AC243972.2, OR10G1P.
- chr14:42,259,731–46,651,781, 47 genes, copy number 23: AL445074.1, AL442163.1, AL450442.1, AL442163.2, AL442163.3, YWHAQP1, AL163153.1, TUBBP3, HNRNPUP1, AL583809.1, KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303, LINC00871, RPL10L.
- chr14:47,444,106–47,444,494, 1 gene, copy number 7: RPS15AP3.
- chr14:49,552,633–106,875,071, 1,507 genes, copy number 8 (broad region; genes not listed).
- chr18:10,124,588–10,144,406, 1 gene, copy number 8: AP005271.1.
- chr18:11,326,270–12,658,134, 57 genes, copy number 7 (within-gene range 2–7): AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1, SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, MIR7153, AP001120.1, GNAL, ASNSP6, AP001120.5, AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2, AP001269.3, IMPA2, AP001269.1, AP001542.3, AP001542.1, AP001542.2, AP002414.1, AP002414.4, AP002414.2, AP002414.5, AP002414.3, ANKRD62, RNU6-324P, SDHDP1, PMM2P2, AP005264.5, AP005264.3, AP005264.4, CCDC58P3, AP005264.2, PPIAP56, CIDEA, AP005264.6, AP005264.1, RNU6-170P, TUBB6, AFG3L2, RNU7-129P, PRELID3A, AP001029.1, AP001029.2, SPIRE1, AP001029.3.
- chr19:34,891,605–35,813,299, 77 genes, copy number 12 (broad region; genes not listed).
- chr22:50,015,123–50,801,309, 50 genes, copy number 9: TTLL8, MLC1, MOV10L1, AL034546.1, PANX2, TRABD, AL022328.3, AL022328.4, SELENOO, AL022328.1, AL022328.2, TUBGCP6, HDAC10, MAPK12, MAPK11, PLXNB2, DENND6B, CR559946.1, CR559946.2, PPP6R2, SBF1, ADM2, MIOX, LMF2, NCAPH2, SCO2, U62317.1, TYMP, ODF3B, U62317.3, KLHDC7B-DT, KLHDC7B, SYCE3, CPT1B, CHKB-CPT1B, CHKB, CHKB-DT, U62317.2, MAPK8IP2, ARSA, Y_RNA, AC000050.2, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Autosomal genes at a single copy (total copy number 1): 135. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
